Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAND, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AAND-01A (Primary Tumor).

[page 1 of 2]
Ord #=
SURGICAL PATHOL
Modifiers:

RESULTED

Collect D/T=

(1 of 1)

Surgical Pathology Report

Specimen(s) Received
Right Testis

Clinical History
Not stated.

ICD-O-3
Seminoma NOS 9061/3
Site D Testis NOS 962.9
9/28/14

Gross Description

Right Testis: Received in formalin is a testis with mass weighing 82 grams and measuring 7.5 x 6.5 x 4 cm. The cord measures 4 cm in length x 1 x 0.3 cm. Sectioning the testis reveals the mass to be multilobulated and shows a homogenous, tan-brown, fleshy consistency. No hemorrhage or necrosis is seen. Fragments taken for research. Cassette summary as follows:

- 1 spermatic cord, resection margin
- 2 spermatic cord, mid-section
- 3 spermatic cord, peritesticular region
- 4 tumor with probable normal testicular tissue
- 5-8 representative section of tumor
- 8

Date of Dictation:

Gross Description By:

Microscopic Description
Performed.

Final Pathologic Diagnosis

Right Testis, radical orchiectomy:
Seminoma, unifocal, classic type (7.5 x 6.5 x 4 cm.).
Spermatic cord margin is negative for tumor.

[page 2 of 2]
SURGICAL PATHOL

(Continued)

Acct#:

No lymphovascular invasion.

Tumor is limited to the testis, invades the tunica albuginea but not the tunica vaginalis or spermatic cord.

Pathologic Stage: pT1NXMXS0 (Stage IA)

Attending Pathologist:

***Electronically Signed Out By

Location:

Date Collected:

Criteria:	hw 1/21/14	Yes	No

Source: NCI Genomic Data Commons file a4c42a97-8d97-4722-9136-cc4be5cb6636 (TCGA-XE-AAND-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).